Somatic mutation profile of tumor specimen C3N-02925-01 (aliquot CPT0184530006) from CPTAC case C3N-02925, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 68.8 years (25,138 days).
Specimen C3N-02925-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a24e235-c36d-4ef3-bce4-70a99aee7590.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02925-31 (Blood Derived Normal), aliquot CPT0184590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99202cab-a7a2-4d30-8cab-c03c37e23de1

The open-access MAF lists 52 somatic variants for this specimen: 31 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 19, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 85/469 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.7553C>A p.S2518* | Nonsense Mutation (SNP) | VAF 23/219 reads (11%) | catalogued as COSV101447138; called by muse, mutect2, varscan2
- CDC20B | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1232072108, COSV99696832; called by muse, mutect2
- CELF2 | c.1189G>A p.A397T (on ENST00000416382 / NM_001025077.3; = p.A410T on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/370 reads (6%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.776); catalogued as rs755910221; called by muse, mutect2
- CYP2C9 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 37/421 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs776908257, COSV53247832; called by muse, mutect2
- DNAJB7 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs1471638823; called by muse, mutect2, varscan2
- EGFR | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 38/470 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs150549265, COSV51766389, COSV51769145; called by muse, mutect2
- EPX | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 53/517 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372515743; called by muse, mutect2, varscan2
- JAML | c.202G>A p.E68K (on ENST00000356289 / NM_001098526.2; = p.E58K on NM_153206.3) | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1201784659, COSV52626722; called by muse, mutect2
- KLC4 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 13/400 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.434); catalogued as rs1400508428, COSV99432811; called by muse, mutect2
- NUDT2 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as rs778998275; called by muse, mutect2, varscan2
- PCSK6 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs867788887; called by muse, mutect2
- RYR1 | c.4100C>T p.A1367V | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.443); catalogued as rs1451177752, COSV62106660; called by muse, mutect2, varscan2
- S100A9 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as rs749398418, COSV64199613; called by muse, mutect2
- SBK2 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100705322; called by muse, mutect2
- ZFAT | c.2906C>T p.T969M | Missense Mutation (SNP) | VAF 75/587 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs777595729, COSV64739760; called by muse, mutect2, varscan2
- CA12 | c.845A>T p.E282V | Missense Mutation (SNP) | VAF 35/670 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2
- COL6A1 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 32/641 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CUBN | c.452A>T p.H151L | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- DGKB | c.835A>G p.K279E | Missense Mutation (SNP) | VAF 27/298 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HAX1 | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 77/727 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGSF10 | c.6847G>T p.A2283S | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM | c.4993G>T p.V1665F | Missense Mutation (SNP) | VAF 43/512 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NEK8 | c.1495C>G p.R499G | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.107); called by muse, mutect2
- NOX1 | c.45+2T>A p.X15_splice | Splice Site (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- PCDHB3 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 19/381 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.112); called by muse, mutect2
- POM121 | c.291_319del p.K98Ffs*23 | Frame Shift Del (DEL) | VAF 57/805 reads (7%) | called by mutect2, pindel
- PRDM9 | c.1367T>C p.I456T | Missense Mutation (SNP) | VAF 100/714 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPGRIP1L | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- SMG6 | c.3001C>T p.P1001S | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- URB2 | c.3086T>C p.F1029S | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- ARHGAP31 | c.28C>T p.L10= | Silent (SNP) | VAF 34/538 reads (6%) | called by muse, mutect2
- CCNT2 | c.66G>A p.P22= | Silent (SNP) | VAF 16/299 reads (5%) | catalogued as rs1337389550; called by muse, mutect2
- DCC | c.4005T>C p.C1335= | Silent (SNP) | VAF 35/804 reads (4%) | called by muse, mutect2
- DYNC2I1 | c.2205T>A p.S735= | Silent (SNP) | VAF 23/260 reads (9%) | called by muse, mutect2
- ESPL1 | c.5424G>A p.P1808= | Silent (SNP) | VAF 38/294 reads (13%) | catalogued as rs758970408; called by muse, mutect2, varscan2
- HTATSF1 | c.765C>T p.A255= | Silent (SNP) | VAF 31/283 reads (11%) | catalogued as rs771520314; called by muse, mutect2, varscan2
- KRT28 | c.732C>T p.N244= | Silent (SNP) | VAF 14/244 reads (6%) | catalogued as rs1455845184; called by muse, mutect2
- MAMSTR | c.690C>T p.P230= (on ENST00000318083 / NM_001130915.2; = p.P127= on NM_182574.2) | Silent (SNP) | VAF 17/172 reads (10%) | catalogued as rs1410873620; called by muse, mutect2
- MUC12 | c.13554G>A p.L4518= (on ENST00000379442; = p.L4375= on NM_001164462.1) | Silent (SNP) | VAF 80/501 reads (16%) | catalogued as rs757871668; called by muse, varscan2
- NCSTN | c.2129G>A p.*710= | Silent (SNP) | VAF 58/669 reads (9%) | called by muse, mutect2
- P3H1 | c.1539C>T p.F513= | Silent (SNP) | VAF 54/474 reads (11%) | catalogued as COSV99354908; called by muse, mutect2, varscan2
- POLG | c.1680C>T p.P560= | Silent (SNP) | VAF 12/302 reads (4%) | catalogued as COSV104390447; called by muse, mutect2
- PORCN | c.1077C>T p.Y359= (on ENST00000326194 / NM_203475.3; = p.Y348= on NM_022825.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 74/642 reads (12%) | catalogued as rs370844692, CM093034, CM105158; called by muse, mutect2, varscan2
- PPP1R9A | c.2952C>T p.A984= | Silent (SNP) | VAF 24/310 reads (8%) | catalogued as rs777496869; called by muse, mutect2
- PRAMEF17 | c.1167C>T p.T389= | Silent (SNP) | VAF 84/862 reads (10%) | catalogued as rs575099867; called by muse, mutect2
- SH3BP2 | c.1449A>G p.G483= | Silent (SNP) | VAF 39/626 reads (6%) | called by muse, mutect2
- TMEM250 | c.276C>T p.R92= | Silent (SNP) | VAF 64/530 reads (12%) | catalogued as rs755411670; called by muse, mutect2, varscan2
- ZNF540 | c.339G>A p.L113= | Silent (SNP) | VAF 21/222 reads (9%) | called by muse, mutect2, varscan2
- ZNF711 | c.1623G>A p.R541= | Silent (SNP) | VAF 23/219 reads (11%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.1845+3203A>G | Intron (SNP) | VAF 16/163 reads (10%) | called by muse, mutect2, varscan2
- PSAT1 | c.-52C>A | 5'UTR (SNP) | VAF 26/548 reads (5%) | called by muse, mutect2
